Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-AA64, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-AA64-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Adenocarcinoma, intestinal 8144/3
Site: Cardia NOS C16.0
9/23/2014

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

"Stomach , tail of pancreas, spleen and omentum":

- . Moderately differentiated adenocarcinoma, invasive and ulcerated, intestinal pattern of Laurén
- . Size of tumor: 5.0 x 5.0 x 0.9cm
- . Depth of infiltration: up to the perigastric adipose tissue
- . Sanguineous vascular invasion: not detected
- . Lymphatic vascular invasion: not detected
- . Perineural invasion: not detected
- . Adjacent mucosa: an intense chronic inactive gastritis with complete intestinal metaplasia
- . Surgical margins free of neoplastic involvement
- . 15 lymph nodes from the adjacent adipose tissue were dissected, 6 of them are compromised by neoplasia (6/15), with capsular leakage, distributed as follows:
- Nodes from the lesser curvature: 4/10
- Nodes from the greater curvature: 1/2
- Nodes from peri-splenic hilum adipose tissue: 1/3. Presence of neoplastic infiltration in adipose tissue measuring 1.8 x 1.5 x 1.5cm
- . Segment of the pancreatic parenchyma without histological particularities
- . Omentum: mature adipose tissue
- . Spleen: no histological particularities

"Esophageal margin":

- . Free of neoplasia

"Pancreatic capsule":

- . Adipose tissue without atypias

"Nodule from chain 8p":

- . Presence of 2 lymph nodes free of tumor (0/2)

"Celiac trunk":

- . Presence of 2 lymph nodes free of tumor (0/2)

"Retroperitoneum":

- . Fibroadipous tissue free of neoplasia

[page 2 of 2]
"Gallbladder" :
. Moderate chronic cholecystitis

Source: NCI Genomic Data Commons file 94e22316-d1ce-4308-a2d5-e71827f678c7 (TCGA-VQ-AA64.601D9B1D-C6CC-49E5-A0DC-0DFC293B2BD7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).